Gene-level copy-number profile of tumor specimen TCGA-D7-6527-01A from TCGA case TCGA-D7-6527, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 62.4 years (22,793 days).
Specimen TCGA-D7-6527-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.1d99ebdd-bf1c-4473-b8c4-99c1700296a6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D7-6527-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 831 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6b37d6de-b19f-48fd-8f72-4df4b2d20ed7

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 459; copy number 2: 869; copy number 3: 8,008; copy number 4: 19,460; copy number 5: 10,565; copy number 6: 11,645; copy number 7: 2,370; copy number 8: 4,737; copy number 9: 589; copy number 10: 309; copy number 11: 178; copy number 12: 80; copy number 13: 70; copy number 14: 119; copy number 15: 12; copy number 16: 44; copy number 17: 24; copy number 18: 8; copy number 19: 19; copy number 20: 20; copy number 21: 44; copy number 22: 69; copy number 23: 1; copy number 27: 70; copy number 46: 8; copy number 69: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D7-6527-01A-11D-1799-01): tumor purity 0.46, ploidy 5.06, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,644 genes in 47 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:8,189,824–8,344,167, 7 genes, copy number 10: AL358876.1, LINC01714, RNU1-7P, AL358876.2, RNU6-991P, SLC45A1, Y_RNA.
- chr1:8,424,645–8,435,013, 1 gene, copy number 10: RERE-AS1.
- chr1:58,882,868–59,810,647, 8 genes, copy number 9 (within-gene range 4–9): LINC02777, LINC01358, PHBP3, AL592431.2, AL592431.1, HSD52, AC093424.1, FGGY.
- chr1:61,248,945–63,326,984, 42 genes, copy number 9–16: NFIA-AS1, AC099791.3, AC099791.4, AC099791.1, TM2D1, AC099791.2, PATJ, RNU6-414P, RNU6-1177P, LAMTOR5P1, RN7SL180P, MIR3116-1, MIR3116-2, PIGPP2, RPS15AP7, L1TD1, AL162739.1, Y_RNA, KANK4, RNU6-371P, USP1, DOCK7, AL451044.1, ANGPTL3, AL138847.2, AL138847.1, AC103923.1, ATG4C, AC099794.1, AC099794.2, LINC01739, AL162400.3, AL162400.1, AL162400.2, AC096543.1, LINC00466, RNA5SP49, AC096543.2, RPSAP65, FOXD3-AS1, FOXD3, MIR6068.
- chr1:65,792,514–66,374,579, 3 genes, copy number 9 (within-gene range 4–9): PDE4B, PDE4B-AS1, RNU4-88P.
- chr1:67,138,907–67,833,467, 15 genes, copy number 14 (within-gene range 4–14): IL23R, RNU6-586P, RNU4ATAC4P, DNAJB6P4, IL12RB2, SERBP1, RNU6-387P, LINC01702, RNU6-1031P, AL590559.1, RN7SL392P, HNRNPCP9, GADD45A, GNG12, RNU7-80P.
- chr1:99,263,953–105,893,517, 86 genes, copy number 9 (broad region; genes not listed).
- chr1:114,769,479–115,368,072, 10 genes, copy number 9: SIKE1, NR1H5P, SYCP1, TSHB, TSPAN2, LINC01765, AL049825.1, NGF-AS1, NGF, AL512638.3.
- chr1:117,549,415–121,580,524, 92 genes, copy number 10 (broad region; genes not listed).
- chr1:218,881,600–219,297,668, 8 genes, copy number 11: NXNP1, LINC01710, LYPLAL1-DT, LYPLAL1, RIMKLBP2, AL360093.1, AC096642.1, AC096642.2.
- chr1:227,264,776–227,431,035, 4 genes, copy number 12 (within-gene range 8–12): AL627308.2, AL627308.3, LINC01641, NUCKS1P1.
- chr1:234,724,042–248,919,946, 336 genes, copy number 9–16 (broad region; genes not listed).
- chr2:172,735,274–175,168,382, 46 genes, copy number 10–18 (within-gene range 5–18): RAPGEF4, ALDH7A1P2, MAP3K20, MAP3K20-AS1, RPS2P18, AC092573.1, CDCA7, JPT1P1, CBY1P1, PPIAP66, AC013410.1, AC013410.2, AC106900.1, RPL5P7, SP3, AC016737.1, AC016737.2, LINC01960, RPSAP24, OLA1, AC013467.1, RN7SL65P, Y_RNA, LRRC2P1, HNRNPA1P39, LINC01305, AC018470.1, SP9, CIR1, SCRN3, GPR155, AC010894.1, RPA3P1, AC010894.4, AC010894.2, RNU6-5P, WIPF1, AC010894.3, H3P6, CHRNA1, CHN1, RNU6-763P, RNU6-1290P, RPL21P31, ATF2, AC007435.1.
- chr2:176,495,255–177,164,656, 14 genes, copy number 12 (within-gene range 5–12): LINC01117, AC017048.1, AC017048.2, MIR1246, AC017048.3, LINC01116, RNU6ATAC14P, AC092162.2, FUCA1P1, AC092162.1, AC092162.3, AC073636.1, RNU6-187P, AC074286.1.
- chr2:178,194,481–181,409,321, 41 genes, copy number 14–20 (within-gene range 7–20): OSBPL6, CHROMR, PRKRA, PJVK, NUDCP2, FKBP7, PLEKHA3, TTN-AS1, TTN, AC009948.2, AC009948.1, AC009948.3, AC010680.3, AC010680.2, AC010680.4, AC010680.5, AC010680.1, AC092640.1, CCDC141, RNU7-104P, RPS6P2, SESTD1, AC093911.1, RAD52P1, ZNF385B, TXNL4AP1, MIR1258, AC096587.2, AC096587.1, CWC22, AC012669.1, AC009478.1, SCHLAP1, AC104820.1, FTH1P20, RPL27AP3, UBE2E3, AC104076.1, AC068196.1, LINC01934, MIR4437.
- chr3:11,745–4,467,273, 37 genes, copy number 10 (within-gene range 7–10): LINC01986, AC066595.1, CHL1-AS2, AC066595.2, CHL1, RNU6-1194P, RPS8P6, CHL1-AS1, AC087428.1, LINC01266, RPSAP32, AC090044.1, AC087430.1, RN7SL120P, CNTN6, CRB3P1, RPL23AP38, RPL23AP39, RPL21P17, AC018814.1, RN7SKP144, CNTN4, CNTN4-AS2, AC087427.1, HINT2P1, DNAJC19P4, CNTN4-AS1, IL5RA, AC024060.1, TRNT1, CRBN, AC024060.2, AC034195.1, SUMF1, LRRN1, AC023480.1, PNPT1P1.
- chr3:4,749,192–9,363,053, 47 genes, copy number 10 (within-gene range 8–10): EGOT, AC018816.2, AC018816.1, BHLHE40-AS1, BHLHE40, RNF10P1, UBTFL8, Y_RNA, AC090955.1, ARL8B, AC026202.2, AC026202.3, EDEM1, MIR4790, RN7SL553P, AC026202.1, AC087857.1, AC026167.1, AC027119.1, AC069277.1, GRM7-AS3, AC069277.2, GRM7, MRPS36P1, GRM7-AS2, AC066585.1, GRM7-AS1, AC077690.1, LMCD1-AS1, AC018832.1, AC023481.1, RNU4ATAC17P, LMCD1, AC034187.1, SSUH2, OR7E122P, CAV3, OXTR, RAD18, AC034186.2, AC034186.1, SRGAP3, SRGAP3-AS1, AC037193.1, SRGAP3-AS2, SRGAP3-AS3, SRGAP3-AS4.
- chr3:13,816,258–14,773,036, 24 genes, copy number 9: WNT7A, VN1R20P, FGD5P1, TPRXL, AC090004.2, VN1R21P, CHCHD4, TMEM43, AC090004.1, XPC-AS1, XPC, LSM3, AC093496.1, LINC01267, RNA5SP124, SLC6A6, GRIP2, RNU6-905P, RHBDF1P1, AC090952.2, AC090952.1, CCDC174, C3orf20, AC090957.1.
- chr3:18,954,943–20,186,206, 14 genes, copy number 20: RNU6-138P, KCNH8, MIR4791, AC061958.1, EFHB, HSPA8P18, RAB5A, PP2D1, RNU4-85P, SAP18P3, RPL39P18, KAT2B, MIR3135A, SGO1.
- chr3:30,606,601–41,962,130, 189 genes, copy number 9–22 (within-gene range 5–22) (broad region; genes not listed).
- chr3:45,823,316–46,710,886, 29 genes, copy number 10: LZTFL1, AC099782.1, SDHDP4, CCR9, Y_RNA, FYCO1, CXCR6, XCR1, NRBF2P2, FLT1P1, CCR3, CCR1, UQCRC2P1, CCR2, CCR5AS, CCR5, CCRL2, LINC02009, LTF, RTP3, LRRC2, LRRC2-AS1, TDGF1, AC104304.2, FAM240A, AC104304.3, AC104304.1, ALS2CL, TMIE.
- chr3:46,712,117–46,750,891, 3 genes, copy number 10: PRSS50, PRSS46P, PRSS45P.
- chr3:54,874,605–54,967,088, 2 genes, copy number 14: CACNA2D3-AS1, LRTM1.
- chr3:62,814,382–62,926,882, 2 genes, copy number 22: RNU6-139P, AC096915.1.
- chr5:2,261,859–4,041,764, 16 genes, copy number 11–16: AC092266.1, LSINCT5, AC091891.1, IRX2, C5orf38, AC116359.1, AC094105.1, AC094105.2, LINC01377, LINC01019, LINC02162, LINC01017, IRX1, AC016595.1, AC025773.1, AC025187.1.
- chr5:19,233,366–29,600,868, 94 genes, copy number 13–19 (broad region; genes not listed).
- chr5:144,170,873–144,535,670, 6 genes, copy number 18–22 (within-gene range 4–22): KCTD16, AC008652.1, AC109441.1, CKS1BP5, AC008716.1, RN7SKP246.
- chr5:149,141,483–153,223,543, 96 genes, copy number 12–22 (within-gene range 3–22) (broad region; genes not listed).
- chr5:153,887,428–155,398,353, 32 genes, copy number 10–12: LINC01861, AC091962.1, FAM114A2, MFAP3, GALNT10, SAP30L-AS1, HNRNPA3P7, AC008625.1, MIR1294, RN7SL655P, SAP30L, HAND1, AC026688.2, AC026688.1, CIR1P1, MIR3141, MIR1303, Y_RNA, LARP1, RN7SL803P, AC008379.1, FAXDC2, Metazoa_SRP, MIR378H, CNOT8, GEMIN5, MRPL22, AC008410.1, KIF4B, AC010476.2, AC010476.1, AC010591.1.
- chr6:41,026,895–41,350,889, 21 genes, copy number 10: UNC5CL, OARD1, TSPO2, APOBEC2, NFYA, AL031778.1, ADCY10P1, TREML1, TREM2, TREML2, TREML3P, TREML4, RNA5SP207, TREML5P, AL391903.2, AL391903.3, TREM1, AL391903.1, RNU6-643P, AL672212.1, NCR2.
- chr7:75,395,063–76,650,897, 44 genes, copy number 27: TRIM73, NSUN5P1, POM121C, AC211429.1, SPDYE5, PMS2P3, Y_RNA, HIP1, AC004491.1, CCL26, CCL24, AC005102.1, RHBDD2, POR, MIR4651, RPL7L1P3, SNORA14A, TMEM120A, STYXL1, AC006330.1, MDH2, AC005077.4, RNU6-863P, GTF2IP7, AC005077.2, AC005077.1, AC005077.3, SRRM3, HSPB1, YWHAG, PPIAP81, SSC4D, ZP3, DTX2, FDPSP2, AC005522.1, UPK3B, AC004980.4, Y_RNA, AC004980.3, SPDYE16, AC004980.1, POMZP3, AC004980.2.
- chr7:102,433,106–103,989,658, 47 genes, copy number 9–27 (within-gene range 6–27): ORAI2, ALKBH4, LRWD1, MIR5090, MIR4467, POLR2J, RASA4B, POLR2J3, UPK3BL2, AC093668.1, SPDYE2, POLR2J3, RASA4, AC105052.4, AC105052.1, UPK3BL1, AC105052.3, SPDYE2B, POLR2J2, RASA4DP, AC105052.5, FAM185A, AC105052.2, FBXL13, RNU6-1136P, RN7SKP198, LRRC17, NFE4, AC073127.1, ARMC10, CRYZP1, NAPEPLD, AC007683.1, RPL23AP95, AC007683.3, DPY19L2P2, S100A11P1, PMPCB, DNAJC2, PSMC2, RPS29P16, SLC26A5, Y_RNA, Y_RNA, AC005064.1, RELN, RN7SKP86.
- chr7:158,719,730–159,030,195, 5 genes, copy number 9–23: AC019084.1, ESYT2, DYNC2I1, AC004863.1, LINC00689.
- chr12:104,117,086–104,350,307, 8 genes, copy number 12: NFYB, RNA5SP370, LINC02385, AC089983.2, TXNRD1, AC089983.1, RPL18AP3, EID3.
- chr18:21,529,284–23,437,961, 44 genes, copy number 21 (within-gene range 6–21): ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA, CABLES1, TMEM241, AC011731.1.
- chr19:22,925,377–23,003,176, 3 genes, copy number 15: AC022145.2, ZNF728, BNIP3P36.
- chr19:29,698,886–30,228,715, 15 genes, copy number 16 (within-gene range 4–16): C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1.
- chr19:46,533,669–46,850,846, 22 genes, copy number 17: AC011551.1, GAPDHP38, CALM3, AC093503.1, PTGIR, GNG8, AC093503.2, DACT3, DACT3-AS1, PRKD2, RN7SL364P, MIR320E, STRN4, AC008635.1, Y_RNA, FKRP, SLC1A5, AC008622.2, AC008622.3, HNRNPMP2, AC008622.1, AP2S1.
- chr19:50,758,382–51,826,190, 102 genes, copy number 11 (within-gene range 4–11) (broad region; genes not listed).
- chr20:53,255,979–55,075,140, 22 genes, copy number 46–69 (within-gene range 6–69): AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1, DOK5, RNU4ATAC7P, RPL12P4.

Autosomal genes at a single copy (total copy number 1): 459. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
